Surgical pathology report (de-identified scan), TCGA case TCGA-KF-A41W, project TCGA-SARC (Sarcoma), tissue source site Christiana Healthcare, specimen TCGA-KF-A41W-01A (Primary Tumor).

[page 1 of 2]
Final Surgical Pathology Report

ICD-O-3

leiomyosarcoma, NOS
8890/3

Site: Uterus, NOS

C55.9

7-23-12 ED

Procedure:

Diagnosis

- A. Uterus, ovaries and fallopian tubes, hysterectomy and bilateral salpingo-oophorectomy: Leiomyosarcoma, moderate to high-grade, 8.5 cm in greatest dimension, limited to the uterus (pT1b).
- B. Lymph node, left pelvic, regional resection: Six negative lymph nodes (0/6).
- C. Lymph node, left periaortic, regional resection: Six negative lymph nodes (0/6).
- D. Lymph node, right pelvic, regional resection: Eight negative lymph nodes (0/8).
- E. Lymph node, right periaortic, regional resection: Four negative lymph nodes (0/4).

Microscopic Description:

Histologic type: Leiomyosarcoma

Histologic grade: Moderate to high grade

Primary tumor (pT) TNM (FIGO): 8.5 cm in greatest dimension, limited to the uterus (pT1b)

Margins of resection: Negative

Vascular invasion: Not identified

Regional lymph nodes (pN): Twenty-four negative lymph nodes (0/24).

Other findings: Unremarkable ovaries and fallopian tubes; cervix without dysplasia; endometrial cystic atrophy with polyp.

Comments: Microscopic examination shows a hypercellular tumor composed of spindle cells resembling smooth muscle, with moderate to severe pleomorphism, geographic necrosis, mitotic activity that is greater than 10 per 10 high power fields in some areas, and an infiltrative border with the myometrium. Findings morphologically are most compatible with leiomyosarcoma. Immunostaining supports the diagnosis, with scattered positive staining with smooth muscle actin, positive staining with CD10, and negative staining with desmin, c-kit and S-100.

Case also reviewed by

5, 4x3, 20x5

[A few of the antibodies used in our laboratory may be classified as analyte specific reagents. These antibodies are monitored and controlled in our laboratory and their performance for in vitro diagnosis is well described in the medical literature. They have not been cleared or approved by the FDA.]

Specimen

- A. Uterus, cervix, bilateral tubes and ovaries
- B. Left pelvic lymph node
- C. Left periaortic lymph node
- D. Right pelvic lymph node
- E. Right periaortic lymph node

Clinical Information

Uterine sarcoma, sent for tissue procurement

[page 2 of 2]
Intraoperative Consultation

A) Uterus, cervix, fallopian tubes and ovaries, excision: Spindle cell neoplasm suspicious for a leiomyosarcoma.

Gross Description

A. Received fresh labeled "uterus, cervix, bilateral tubes and ovaries" is a 400 g, globoid, 9.5 x 8.5 x 8.5 cm uterine corpus with attached 3.5 cm cervix and bilateral adnexa. The serosa is smooth tan-pink-red.

The annular 3 cm tan-white ectocervix surrounds a 0.8 x 0.2 cm ovoid patent os. Endocervical mucosa is mildly trabecular tan-pink. The distorted uterine cavity is lined by flat tan-pink endometrium averaging 0.2 cm. The cavity is distorted by a submucosal/intramural 8.5 x 7.8 x 7.0 cm focally necrotic firm tan-white nodular lesion. A frozen section is performed (two blocks frozen). The uterine cavity contains a moderate amount of friable red brown debris. A portion of the nodular lesion is submitted for tissue procurement as requested. The myometrium is smooth tan-pink and measures up to 1.8 cm in thickness. Bilaterally, the cerebriform rubbery tan gold ovary is average 1.8 x 1.3 x 0.9 cm. The stroma of both ovaries is tan-pink with identifiable corpora albicantia. The fimbriated tan-pink right and left fallopian tubes are 7 cm in length and 0.5 cm in diameter. The lumina are pinpoint and stellate. RS 18. Summary: 1 and 2 - anterior cervix, continuity inked blue. 3 - anterior endomyometrium, 4 and 5 - posterior cervix, continuity inked black, 6 - posterior endomyometrium, 7 through 10 - lesion to endometrial surface, 11 and 12, 13 and 14 - lesion to serosal surface of specimen, 15 and 16 - additional sections of lesion to myometrium, 17 - right adnexa, 18 - left adnexa

B. Received fresh labeled "left pelvic lymph node" is a 5.5 x 4.5 x 1.7 cm aggregate of soft, lobulated tan gold adipose tissue. Several slightly rubbery tan gold-pink tissues in keeping with lymph nodes measuring up to 2.3 cm are recovered. The lymphoid tissues are entirely submitted.

Summary: 1 - 2 lymph nodes, 2 through 5 - 1 bisected lymph node per cassette

C. Received fresh labeled "left periaortic lymph node" is a 3.3 x 2.3 x 1.3 cm aggregate of soft, lobulated tan gold adipose tissue. A few slightly rubbery tan gold-pink tissues in keeping with lymph nodes measuring up to 1.0 cm are recovered. The lymphoid tissues are entirely submitted.

Summary: 1 - 5 lymph nodes, 2 - 1 bisected lymph node

D. Received fresh labeled "right pelvic lymph node" is a 4.2 x 4.0 x 1.7 cm aggregate of soft, lobulated tan gold adipose tissue. Several slightly rubbery tan gold-pink tissues in keeping with lymph nodes measuring up to 3.7 cm in greatest dimension are recovered. The lymphoid tissues are entirely submitted.

Summary: 1 - 4 lymph nodes, 2 - 2 lymph nodes, 3 - 1 bisected lymph node, 4 and 5 - 1 bisected lymph node

E. Received fresh labeled "right periaortic lymph node" is a 2.7 x 2.4 x 1.0 cm aggregate of soft, lobulated tan gold adipose tissue. A few slightly rubbery tan gold-pink tissues in keeping with lymph nodes measuring up to 1.8 cm are recovered. The lymphoid tissues are entirely submitted.

Summary: 1 - 3 lymph nodes, 2 - 1 bisected lymph node

7/18

Source: NCI Genomic Data Commons file 7c06b868-bd7e-4192-9996-43f3474b7677 (TCGA-KF-A41W.EFF7015E-8729-4B1B-A678-D133256E4658.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).